Somatic mutation profile of tumor specimen TCGA-ER-A19G-06A (aliquot TCGA-ER-A19G-06A-11D-A196-08) from TCGA case TCGA-ER-A19G, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.7 years (22,528 days).
Specimen TCGA-ER-A19G-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b87583b-8508-4b14-aa20-da057efa72d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19G-10A (Blood Derived Normal), aliquot TCGA-ER-A19G-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/911a5d7d-a20d-4497-bef6-7e1447c3ee90

The open-access MAF lists 629 somatic variants for this specimen: 403 protein-altering or splice-affecting, 215 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 215, Nonsense Mutation 24, Frame Shift Del 8, Splice Site 6, RNA 6, Splice Region 5, 5'UTR 2, Frame Shift Ins 2, Intron 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); catalogued as CS1511368, COSV62562857; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA1 | c.3008_3009del p.F1003* | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | catalogued as rs80357617; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRD4 | c.3194C>G p.P1065R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54587010, COSV99651604; called by mutect2, varscan2
- KCNJ8 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 38/91 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV53715303; called by muse, mutect2, varscan2
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs771385885, COSV66071404; called by muse, mutect2, varscan2
- ABCA4 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM003378, COSV64671224; called by muse, mutect2, varscan2
- ABL2 | c.435G>A p.W145* (on ENST00000502732 / NM_007314.4; = p.W130* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV61017076; called by muse, mutect2, varscan2
- ACE | c.2912+2T>C p.X971_splice | Splice Site (SNP) | VAF 29/50 reads (58%) | catalogued as COSV52009240; called by muse, mutect2, varscan2
- ACOX1 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV53134175; called by muse, mutect2, varscan2
- ACVR1C | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as COSV54647492; called by muse, mutect2, varscan2
- ADAM10 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53050102, COSV53052785; called by muse, mutect2, varscan2
- ADAMTS18 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs769577910, COSV51400683; called by muse, mutect2, varscan2
- ADAMTS6 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV66861628; called by muse, mutect2, varscan2
- ADCY8 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.76); catalogued as COSV53914571, COSV99653398; called by mutect2, varscan2
- ADGRB3 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53238942, COSV53247980; called by muse, varscan2
- ADGRG3 | c.89A>C p.N30T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV59651697; called by muse, mutect2, varscan2
- AGK | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as COSV100814712, COSV62595057; called by muse, mutect2, varscan2
- AGRP | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs752295493, COSV52098868; called by muse, mutect2, varscan2
- ALB | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1259433502, COSV55739644; called by muse, mutect2, varscan2
- ALDOB | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764927361, COSV66398143; called by muse, mutect2, varscan2
- ALDOC | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52025323; called by muse, varscan2
- ALMS1 | c.10090C>T p.Q3364* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV52513888; called by muse, mutect2, varscan2
- ALPP | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229304863, COSV67395766; called by muse, varscan2
- AMY2A | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV101340689; called by mutect2, varscan2
- ANK2 | c.11771C>T p.P3924L | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV52171450; called by muse, mutect2, varscan2
- ANKFN1 | c.258dup p.H87Tfs*2 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs1322720501; called by mutect2, varscan2
- ANKS1B | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs866496524, COSV59119316, COSV59121585; called by muse, mutect2, varscan2
- APOB | c.3017G>A p.R1006K | Missense Mutation (SNP) | VAF 126/326 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51942061; called by muse, varscan2
- AQR | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV50029552; called by muse, mutect2, varscan2
- ARFGEF1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as rs144506580, COSV51611838; called by muse, mutect2, varscan2
- ARHGEF4 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); catalogued as COSV100388906; called by muse, mutect2, varscan2
- ARID3B | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV60558188; called by muse, mutect2, varscan2
- ASXL1 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as COSV60112476; called by muse, mutect2, varscan2
- ATG2A | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1487031333, COSV65967412; called by muse, mutect2, varscan2
- ATIC | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs903756807, COSV52692611; called by muse, mutect2, varscan2
- ATP1A3 | c.1330C>T p.P444S (on ENST00000545399 / NM_001256214.2; = p.P431S on NM_152296.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV57488375, COSV57489031; called by muse, mutect2, varscan2
- ATP2B2 | c.2365G>A p.V789I (on ENST00000352432; = p.V755I on NM_001683.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59500787; called by muse, mutect2, varscan2
- ATP6V0A4 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59477522; called by muse, mutect2, varscan2
- BAIAP2 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV58337252; called by muse, mutect2, varscan2
- BCAM | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs979776206, COSV54300443, COSV54301154, COSV54303275; called by muse, mutect2, varscan2
- BCO1 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs372527154; called by muse, varscan2
- BRF1 | c.1630C>G p.R544G | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100526946, COSV59270637; called by muse, mutect2, varscan2
- BTBD8 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV61546948; called by muse, mutect2, varscan2
- C12orf50 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.568); catalogued as rs759969576, COSV53896713; called by muse, mutect2, varscan2
- C16orf90 | c.64G>A p.G22R (on ENST00000399645 / NM_001353385.2; = p.M1? on NM_001080524.2) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV68714527, COSV68714598; called by mutect2, varscan2
- C1orf198 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.153); catalogued as COSV64175830; called by muse, mutect2, varscan2
- C2orf78 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV68517970; called by muse, mutect2, varscan2
- CACNA1A | c.1350T>C p.G450= | Splice Region (SNP) | VAF 3/16 reads (19%) | catalogued as COSV64202807; called by muse, mutect2
- CACNB4 | c.886A>C p.I296L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV52392994; called by muse, mutect2, varscan2
- CAPN2 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV54337505; called by muse, varscan2
- CARD11 | c.3258C>T p.F1086= | Splice Region (SNP) | VAF 40/72 reads (56%) | catalogued as COSV67800372; called by mutect2, varscan2
- CCDC153 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV59540629; called by muse, mutect2, varscan2
- CCDC185 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1381815337, COSV64821283; called by muse, mutect2, varscan2
- CD163L1 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.447); catalogued as COSV58013995; called by muse, mutect2, varscan2
- CD1B | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs1557823039, COSV63804161, COSV63804598; called by muse, mutect2, varscan2
- CDCA2 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV57946920; called by mutect2, varscan2
- CEP126 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV54827358; called by muse, mutect2, varscan2
- CEP128 | c.1831C>T p.H611Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV55382098; called by mutect2, varscan2
- CETN1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs143489830, COSV59121030; called by muse, mutect2, varscan2
- CFAP46 | c.7134G>T p.K2378N | Missense Mutation (SNP) | VAF 84/126 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV54154705; called by mutect2, varscan2
- CFAP74 | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 88/190 reads (46%) | catalogued as COSV54569954, COSV54571019; called by muse, mutect2, varscan2
- CHEK1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs369248914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHERP | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52225745; called by muse, varscan2
- CHIC1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100998272, COSV65156572; called by muse, mutect2, varscan2
- CHRM3 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55085005, COSV99697190; called by muse, mutect2, varscan2
- CHST10 | c.719T>C p.F240S | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51806100; called by muse, mutect2, varscan2
- CLDN10 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV54825024; called by mutect2, varscan2
- CLEC4G | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs766542690, COSV61003658; called by muse, mutect2
- CLPTM1 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 77/182 reads (42%) | catalogued as COSV61612336; called by mutect2, varscan2
- CLVS1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as rs1190700549, COSV57975418; called by muse, mutect2, varscan2
- CNTN2 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); catalogued as COSV59351168; called by muse, mutect2, varscan2
- CNTN5 | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327305; called by muse, varscan2
- CNTNAP2 | c.961T>G p.F321V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62208497, COSV62211017; called by muse, mutect2, varscan2
- CNTNAP5 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs765130255, COSV70494484; called by muse, mutect2, varscan2
- COL15A1 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.028); catalogued as COSV66646870; called by muse, varscan2
- COL22A1 | c.3935G>A p.G1312E | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57345176; called by muse, mutect2, varscan2
- COL4A2 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1383709300, COSV64630245; called by muse, mutect2, varscan2
- COL4A3 | c.2953G>A p.G985R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100516897; called by muse, mutect2, varscan2
- COL4A3 | c.4387G>A p.G1463R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67414610; called by muse, mutect2, varscan2
- COQ4 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55957483; called by mutect2, varscan2
- COQ8A | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs863223882, COSV100825862; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPN2 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as rs267599742, COSV60470952; called by muse, mutect2, varscan2
- CREG1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs183830710, COSV104423559, COSV65148591; called by muse, mutect2, varscan2
- CRTC2 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV57843957; called by muse, mutect2, varscan2
- CSMD3 | c.2018G>A p.G673E (on ENST00000297405 / NM_001363185.1; = p.G569E on NM_052900.3) | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52117004; called by muse, mutect2, varscan2
- CSRNP3 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58781194; called by muse, mutect2, varscan2
- CT83 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64141204; called by muse, mutect2, varscan2
- CUL7 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54819173, COSV54821362; called by muse, mutect2, varscan2
- DCLK2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as COSV56206947; called by muse, mutect2, varscan2
- DEFA3 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV59935267; called by muse, varscan2
- DENND4A | c.4556C>T p.S1519F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.804); catalogued as COSV101475466, COSV71266315; called by muse, mutect2, varscan2
- DISC1 | c.1817A>T p.D606V | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54411487; called by muse, mutect2, varscan2
- DLGAP1 | c.2057G>A p.C686Y | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV59816399; called by muse, mutect2, varscan2
- DMXL1 | c.8611C>T p.L2871F | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288088180, COSV60715560; called by muse, mutect2, varscan2
- DNAH1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as COSV70231490; called by muse, mutect2, varscan2
- DNAH2 | c.2216T>G p.M739R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66721952; called by muse, mutect2, varscan2
- DNAH5 | c.11440G>A p.E3814K | Missense Mutation (SNP) | VAF 94/124 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54232748; called by muse, mutect2, varscan2
- DNAH5 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 105/216 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54220499, COSV54236611; called by muse, mutect2, varscan2
- DNAH8 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV59460453; called by muse, mutect2, varscan2
- DNAH9 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs762435304, COSV52358774; called by mutect2, varscan2
- DNAJB7 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 160/201 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53422439; called by muse, mutect2, varscan2
- DNAJC15 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64872560; called by muse, mutect2, varscan2
- DNAJC6 | c.1831C>T p.L611F | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV54777660; called by muse, mutect2, varscan2
- DNHD1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54438837; called by muse, mutect2, varscan2
- DNM3 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62457191; called by muse, mutect2, varscan2
- DONSON | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV51663318; called by muse, mutect2, varscan2
- DRD2 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV60759846; called by muse, mutect2, varscan2
- DSCAM | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.756); catalogued as COSV68030379; called by muse, mutect2, varscan2
- DSG3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs772960249, COSV57124134; called by muse, mutect2, varscan2
- DTD2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.045); catalogued as COSV60428117; called by mutect2, varscan2
- DUSP18 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 122/156 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV58181231; called by muse, mutect2, varscan2
- ECRG4 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV53001369; called by muse, mutect2, varscan2
- EFHB | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as COSV55545742; called by muse, mutect2, varscan2
- EPPK1 | c.1533G>A p.W511* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV73261769; called by muse, mutect2, varscan2
- FAM124B | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV66272759; called by muse, mutect2, varscan2
- FAM221A | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1164040634, COSV61388125; called by muse, mutect2, varscan2
- FAM47C | c.226T>A p.F76I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.681); catalogued as COSV63728068; called by muse, mutect2, varscan2
- FAM83B | c.2404A>G p.S802G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.939); catalogued as rs1158526784, COSV60923938; called by muse, mutect2, varscan2
- FASLG | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as COSV60680040; called by muse, mutect2, varscan2
- FBXO40 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328583816, COSV57525421; called by muse, mutect2, varscan2
- FCER2 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1298993939, COSV100689682; called by muse, mutect2, varscan2
- FCRL4 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1160055254, COSV54863586; called by mutect2, varscan2
- FLG | c.9707C>T p.S3236F | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs532804294, COSV64244053; called by muse, mutect2, varscan2
- FLG | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV64244057; called by muse, mutect2, varscan2
- FRYL | c.5549C>T p.S1850F | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1472809698, COSV51952265; called by muse, mutect2, varscan2
- FSD1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.481); catalogued as rs777105230, COSV55697003; called by muse, varscan2
- FSIP2 | c.16639A>C p.S5547R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV58091152; called by muse, mutect2, varscan2
- FZD1 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55311921; called by muse, mutect2, varscan2
- GABRE | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs150837963, COSV64820287; called by muse, mutect2, varscan2
- GAGE10 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 88/132 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs376577624, COSV68164020, COSV68164057; called by muse, mutect2, varscan2
- GALNT10 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs1306080842, COSV51729116; called by muse, mutect2, varscan2
- GALNT12 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749861818, COSV66662572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAMT | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52039955; called by muse, mutect2, varscan2
- GDF10 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); catalogued as rs1040878270; called by mutect2, varscan2
- GDPD2 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 30/44 reads (68%) | catalogued as rs761340605, COSV100978651, COSV65533500; called by muse, mutect2, varscan2
- GJA5 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV54785067; called by muse, mutect2, varscan2
- GJB3 | c.688T>C p.S230P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV64904733; called by muse, mutect2, varscan2
- GLG1 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs774350675, COSV52669858; called by muse, mutect2, varscan2
- GLI3 | c.3355G>T p.D1119Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs374088219, COSV67890751; called by muse, mutect2, varscan2
- GLIPR1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs760375651, COSV56990545; called by muse, mutect2, varscan2
- GNAS | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV58339599; called by muse, mutect2, varscan2
- GNAS | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.916); catalogued as COSV58338955; called by muse, mutect2, varscan2
- GPBP1L1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV51970767; called by mutect2, varscan2
- GPR137B | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63991275; called by muse, mutect2, varscan2
- GPR151 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV57038899; called by muse, mutect2, varscan2
- GRAP | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV52413725, COSV52413973; called by muse, mutect2
- GREB1 | c.5722T>A p.S1908T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV99304039; called by muse, varscan2
- GRIK3 | c.2313G>A p.M771I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV66142292; called by muse, mutect2, varscan2
- GSE1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs778445212, COSV53673477; called by mutect2, varscan2
- HADHA | c.70T>G p.Y24D | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV66107959; called by muse, mutect2, varscan2
- HARS1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs769340873, COSV56907864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HBG2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100400571, COSV57963956; called by muse, mutect2, varscan2
- HCAR2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs761914459, COSV61025210; called by muse, mutect2, varscan2
- HCN4 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs146714274; called by muse, mutect2, varscan2
- HDC | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.157); catalogued as COSV51073649; called by muse, mutect2, varscan2
- HDC | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs749851294, COSV51068330; called by muse, mutect2, varscan2
- HECTD1 | c.4396C>T p.P1466S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV67947472; called by muse, mutect2, varscan2
- HHATL | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV60042497; called by muse, mutect2, varscan2
- HIVEP3 | c.2564T>C p.V855A | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56018204; called by muse, mutect2, varscan2
- HOMER2 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1451142252, COSV58487000; called by muse, varscan2
- HPD | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100000263; called by muse, mutect2, varscan2
- HYDIN | c.9917G>A p.R3306Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs578231783, COSV66863806; called by mutect2, varscan2
- IL7 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as COSV55676026; called by muse, mutect2, varscan2
- IMPG1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs1358218204, COSV100886493, COSV64059379; called by mutect2, varscan2
- IMPG2 | c.2833G>A p.G945R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51981092; called by muse, mutect2, varscan2
- INHBC | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV59005604; called by muse, mutect2, varscan2
- ITGAL | c.2744C>T p.T915I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.717); catalogued as rs765387236, COSV63321080; called by muse, mutect2, varscan2
- JAM3 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV54454168; called by muse, mutect2, varscan2
- JHY | c.686T>G p.V229G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56220403; called by muse, mutect2, varscan2
- KCNK5 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.086); catalogued as rs1220265479, COSV100851816, COSV63989108; called by muse, mutect2, varscan2
- KIAA1755 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54078044; called by muse, mutect2, varscan2
- KIF18A | c.588+2T>A p.X196_splice | Splice Site (SNP) | VAF 17/97 reads (18%) | catalogued as COSV54184786; called by muse, mutect2, varscan2
- KIF21B | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as rs267598289, COSV59753464; called by mutect2, varscan2
- KIR3DL3 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1331248128; called by muse, mutect2, varscan2
- KLHL22 | c.1886A>G p.D629G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs1353064383, COSV56733015; called by muse, mutect2, varscan2
- KRT24 | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV52880864; called by muse, mutect2, varscan2
- KRT26 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs750060535, COSV59414813; called by muse, mutect2, varscan2
- KRT74 | c.1112A>G p.E371G | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59772365; called by muse, mutect2, varscan2
- LAMB4 | c.3862G>A p.D1288N | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52723375; called by muse, mutect2, varscan2
- LARP6 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs746873492, COSV54579457; called by muse, mutect2, varscan2
- LGR4 | c.2165C>G p.A722G | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV60821128; called by muse, mutect2, varscan2
- LGR5 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV57006853; called by muse, mutect2, varscan2
- LILRA6 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.691); catalogued as rs1270656179; called by muse, mutect2, varscan2
- LILRB2 | c.916T>G p.C306G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1409275847, COSV58746616; called by muse, mutect2, varscan2
- LRP1B | c.12496C>T p.R4166C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1437399353, COSV67213125; called by muse, mutect2, varscan2
- LRRC4C | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.642); catalogued as COSV53430588; called by muse, mutect2, varscan2
- LRRC66 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV58634959; called by muse, mutect2, varscan2
- LRRK1 | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745327307, COSV52614560; called by muse, mutect2, varscan2
- LRRN3 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145461505, COSV57821496; called by muse, mutect2, varscan2
- LRRTM2 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV51222934; called by muse, mutect2, varscan2
- LTF | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1268592779, COSV51609722; called by muse, mutect2, varscan2
- LTN1 | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV63734301; called by muse, mutect2, varscan2
- MAGEA10 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV54882887; called by muse, mutect2, varscan2
- MDFI | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57822353; called by muse, mutect2, varscan2
- MEIOC | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV63440530; called by muse, mutect2, varscan2
- MGAM | c.3749G>T p.R1250L | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV72074454, COSV72075015; called by muse, mutect2, varscan2
- MICAL2 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV56287145; called by muse, mutect2, varscan2
- MIXL1 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs368158684, COSV64729258; called by mutect2, varscan2
- MORC1 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs781110641, COSV51721883, COSV51727146; called by muse, mutect2, varscan2
- MPRIP | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV100506206, COSV59051757; called by muse, mutect2, varscan2
- MRC2 | c.224A>C p.Q75P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57641583; called by muse, varscan2
- MRC2 | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV57641589; called by muse, mutect2, varscan2
- MUC15 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV55555618; called by muse, mutect2, varscan2
- MUC16 | c.33173C>T p.P11058L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as COSV67477196; called by muse, mutect2, varscan2
- MUC16 | c.24761G>A p.W8254* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV67477199; called by muse, mutect2, varscan2
- MUC16 | c.20674G>A p.E6892K | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.031); catalogued as rs775745092, COSV67477206; called by muse, varscan2
- MUC2 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs762772699; called by muse, mutect2, varscan2
- MUC5B | c.6892C>T p.P2298S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as COSV101500942; called by muse, mutect2, varscan2
- MUC5B | c.6893C>T p.P2298L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1400293940, COSV101500889, COSV71590937; called by muse, mutect2, varscan2
- MYH13 | c.5557G>A p.E1853K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758559636, COSV52834134; called by muse, mutect2, varscan2
- MYH15 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.593); catalogued as COSV56313815; called by muse, mutect2, varscan2
- MYH2 | c.4235C>T p.A1412V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs758731740, COSV55441825; called by muse, mutect2, varscan2
- MYO15A | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV52751672; called by muse, mutect2, varscan2
- MYO16 | c.5246C>T p.S1749F | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV62753554; called by muse, mutect2, varscan2
- NAV3 | c.3052G>C p.D1018H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57092295; called by muse, varscan2
- NDUFB3 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52987622; called by muse, mutect2
- NEIL2 | c.688+1G>A p.X230_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52707233; called by muse, mutect2, varscan2
- NKAIN1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99744824; called by mutect2, varscan2
- NLRP11 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV64085665; called by muse, mutect2, varscan2
- NLRP13 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61622727; called by muse, mutect2, varscan2
- NLRP14 | c.785A>T p.D262V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55069050; called by muse, mutect2, varscan2
- NLRP9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1210150376, COSV60465131; called by muse, mutect2, varscan2
- NOD1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99768606; called by muse, varscan2
- NOS1 | c.3429G>A p.W1143* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV57613590, COSV57615783; called by muse, mutect2, varscan2
- NPAS3 | c.1348C>G p.H450D (on ENST00000356141 / NM_001164749.2; = p.H418D on NM_022123.3) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV60843763; called by muse, mutect2, varscan2
- NPVF | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs773825860, COSV56061012; called by muse, mutect2, varscan2
- NRXN3 | c.2725C>T p.L909F (on ENST00000335750 / NM_001330195.2; = p.L536F on NM_004796.6) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV59769961, COSV59809190; called by muse, mutect2, varscan2
- NYNRIN | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.024); catalogued as COSV101230732; called by mutect2, varscan2
- OAS3 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 32/153 reads (21%) | catalogued as rs752917599, COSV57444390; called by mutect2, varscan2
- ODF1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV53433155; called by muse, mutect2, varscan2
- OR10Q1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV57471016; called by muse, mutect2, varscan2
- OR13H1 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV58547946; called by muse, mutect2, varscan2
- OR14A16 | c.487T>G p.S163A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV100713870; called by mutect2, varscan2
- OR1F1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58961693; called by muse, mutect2, varscan2
- OR1J4 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs552154608, COSV61589594, COSV61590018; called by muse, mutect2, varscan2
- OR1L6 | c.928G>A p.V310I (on ENST00000373684; = p.V274I on NM_001004453.2) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as COSV100491035; called by muse, mutect2, varscan2
- OR2B3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65850900, COSV65851044; called by muse, mutect2
- OR2H1 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1256591948, COSV65810977; called by muse, mutect2, varscan2
- OR2Y1 | c.914G>A p.W305* | Nonsense Mutation (SNP) | VAF 58/128 reads (45%) | catalogued as rs762521444, COSV57137125; called by muse, mutect2, varscan2
- OR4K1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV53459578; called by muse, mutect2, varscan2
- OR4K2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); catalogued as rs756950043, COSV53848625; called by muse, mutect2, varscan2
- OR4Q3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59179306; called by mutect2, varscan2
- OR5R1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV56571496; called by muse, mutect2, varscan2
- OR6C65 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.924); catalogued as rs1213339398, COSV101110170, COSV101110211; called by muse, mutect2, varscan2
- OR6S1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57838237; called by muse, mutect2, varscan2
- OR7D2 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV60138881; called by muse, mutect2, varscan2
- OR7D4 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV58072003; called by muse, mutect2, varscan2
- OTOF | c.1579+1G>A p.X527_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99719347; called by muse, mutect2, varscan2
- OTOF | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99717119, COSV99719348; called by mutect2, varscan2
- OTOL1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV60007487; called by muse, mutect2, varscan2
- PAPPA2 | c.790T>C p.Y264H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs201151658, COSV62781141; called by muse, mutect2, varscan2
- PCDH15 | c.4112G>A p.G1371E | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57340022; called by muse, varscan2
- PCDHA1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65375119; called by muse, mutect2, varscan2
- PCDHA2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.05); catalogued as COSV100973458, COSV65368478; called by muse, mutect2, varscan2
- PCDHA3 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); catalogued as COSV100793578, COSV100793850; called by muse, mutect2, varscan2
- PCDHA3 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); catalogued as rs782186555, COSV63542147; called by mutect2, varscan2
- PCDHB15 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV51076506; called by muse, varscan2
- PCDHB16 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1554282239, COSV53365382; called by muse, mutect2, varscan2
- PCDHGC4 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52743010; called by muse, varscan2
- PCLO | c.11453A>C p.K3818T | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61646664; called by muse, mutect2, varscan2
- PDE10A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866168774, COSV63092169; called by muse, mutect2, varscan2
- PDE11A | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53699896; called by muse, mutect2, varscan2
- PDZRN4 | c.3079C>T p.H1027Y (on ENST00000402685 / NM_001164595.2; = p.H769Y on NM_013377.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as COSV100114206, COSV54207001; called by mutect2, varscan2
- PFKFB1 | c.1211T>C p.F404S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | PolyPhen probably damaging (0.992); catalogued as COSV66628808; called by muse, mutect2, varscan2
- PHACTR2 | c.432A>C p.E144D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV59855982; called by muse, mutect2, varscan2
- PLAC8L1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as COSV61014080; called by muse, mutect2, varscan2
- PLD1 | c.942A>C p.R314S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100579121; called by muse, mutect2, varscan2
- PLD1 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100579124; called by muse, mutect2, varscan2
- PLEKHG5 | c.3123G>A p.S1041= (on ENST00000400915 / NM_001042663.3; = p.S1004= on NM_020631.6) | Splice Region (SNP) | VAF 26/129 reads (20%) | catalogued as COSV61068899; called by muse, mutect2, varscan2
- PLIN4 | c.2954G>A p.S985N (on ENST00000301286; = p.S1000N on NM_001367868.2) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs1191664621, COSV56694076; called by muse, mutect2, varscan2
- PLOD3 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV56183920; called by muse, mutect2, varscan2
- PLS1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV61834534; called by muse, varscan2
- PMFBP1 | c.1761G>A p.M587I (on ENST00000537465; = p.M582I on NM_031293.3) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52822118; called by muse, varscan2
- POP1 | c.2054A>T p.K685I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV62893344; called by muse, mutect2, varscan2
- POU2F2 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV60764809; called by muse, mutect2, varscan2
- PPP1R9A | c.2539G>T p.G847W | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56899585; called by mutect2, varscan2
- PPP2R1A | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs112759633, COSV59046034; called by muse, mutect2, varscan2
- PPP2R2B | c.1018G>A p.D340N (on ENST00000394409; = p.D406N on NM_181674.2) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV60769970; called by muse, mutect2, varscan2
- PPP4R4 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58553640; called by mutect2, varscan2
- PRAMEF14 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1553125637; called by muse, mutect2, varscan2
- PREP | c.1435C>T p.P479S (on ENST00000369110; = p.P545S on NM_002726.5) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.122); catalogued as rs775217938, COSV64870891; called by muse, mutect2, varscan2
- PREX2 | c.3961C>T p.Q1321* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV55781821; called by mutect2, varscan2
- PRKG2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 113/176 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV52327268; called by muse, mutect2, varscan2
- PROKR2 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1222362721, COSV54087542, COSV54088295; called by muse, mutect2, varscan2
- PROSER3 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV56554018; called by muse, varscan2
- PRSS1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61194406; called by muse, varscan2
- PTGFR | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 73/161 reads (45%) | catalogued as COSV66114596; called by muse, mutect2, varscan2
- PTPRT | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746243026, COSV61995239; called by mutect2, varscan2
- PTPRT | c.2852A>G p.Y951C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61995249; called by muse, mutect2
- PXT1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101493388, COSV101493413; called by muse, mutect2, varscan2
- PXT1 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101493414; called by mutect2, varscan2
- RBKS | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100142541; called by mutect2, varscan2
- RBSN | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV53794151; called by mutect2, varscan2
- RHBDL3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746532243, COSV52185662; called by muse, mutect2, varscan2
- RHOBTB2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52569739; called by muse, mutect2, varscan2
- RIMS2 | c.1300C>T p.P434S (on ENST00000666250 / NM_001348490.2; = p.P242S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746820996, COSV51664428; called by muse, mutect2, varscan2
- RNPEP | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 78/175 reads (45%) | catalogued as rs371505001; called by muse, mutect2, varscan2
- ROBO4 | c.2790C>A p.F930L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV60625619; called by muse, mutect2, varscan2
- ROS1 | c.6263C>T p.S2088F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63857295; called by muse, mutect2, varscan2
- RPL5 | c.13A>T p.K5* | Nonsense Mutation (SNP) | VAF 55/100 reads (55%) | catalogued as COSV59873719; called by muse, mutect2, varscan2
- RRM2 | c.658A>C p.T220P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV58817209; called by muse, mutect2, varscan2
- RYR2 | c.4510G>A p.G1504R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100773342; called by muse, mutect2, varscan2
- RYR3 | c.972G>A p.K324= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV66798134, COSV66811319; called by muse, mutect2, varscan2
- SACS | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV66542960; called by muse, mutect2, varscan2
- SAMD12 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1166930890, COSV59048273; called by muse, mutect2, varscan2
- SCN3A | c.3161G>A p.G1054E | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV51815264; called by muse, mutect2, varscan2
- SEMA6C | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV59004910; called by muse, mutect2, varscan2
- SERPINB3 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192622; called by muse, mutect2, varscan2
- SEZ6L | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50669503; called by muse, mutect2, varscan2
- SH3PXD2A | c.1681C>T p.P561S (on ENST00000369774 / NM_001365079.1; = p.P533S on NM_014631.2) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV60118422; called by muse, mutect2, varscan2
- SIGLEC1 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV52466948; called by muse, varscan2
- SIGLEC7 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV58316706, COSV99978962; called by muse, mutect2, varscan2
- SIM1 | c.1469G>A p.W490* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV53493880, COSV53495841; called by muse, mutect2, varscan2
- SLC12A7 | c.3119A>G p.N1040S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV53759126; called by muse, mutect2, varscan2
- SLC24A2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs559651080, COSV53868595; called by muse, mutect2, varscan2
- SLC25A14 | c.28A>T p.I10F | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.161); catalogued as COSV54418929; called by muse, mutect2, varscan2
- SLC35F4 | c.752G>A p.R251K (on ENST00000339762 / NM_001352015.2; = p.R215K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as COSV60265648; called by muse, mutect2, varscan2
- SLC38A4 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255940496, COSV56968851; called by muse, mutect2, varscan2
- SLC9C2 | c.297A>T p.L99F | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV62946846; called by muse, mutect2, varscan2
- SMG7 | c.1033T>C p.C345R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61632543; called by muse, mutect2, varscan2
- SORL1 | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV52757289; called by muse, mutect2, varscan2
- SOS1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV67675465, COSV67676283; called by muse, mutect2, varscan2
- SOX30 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53938205; called by mutect2, varscan2
- SOX6 | c.899-1G>A p.X300_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as COSV57050453; called by muse, mutect2, varscan2
- SPHKAP | c.4025C>T p.S1342L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1167554305, COSV60884767; called by mutect2, varscan2
- SPHKAP | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60884781; called by muse, mutect2, varscan2
- SPOCD1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.792); catalogued as rs748593174, COSV57097627; called by muse, mutect2, varscan2
- SPRY2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs770217072, COSV65701549; called by mutect2, varscan2
- SPTA1 | c.5441A>C p.K1814T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV63756024; called by muse, mutect2, varscan2
- SSPN | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV54381556; called by muse, mutect2, varscan2
- ST6GAL2 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 57/156 reads (37%) | PolyPhen probably damaging (0.999); catalogued as COSV62417252; called by muse, mutect2, varscan2
- STAT3 | c.946T>A p.L316I | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52889595; called by mutect2, varscan2
- STAT4 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100636273; called by muse, mutect2
- STRA6 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.045); catalogued as COSV100121349; called by muse, mutect2, varscan2
- STXBP5L | c.1738C>T p.L580F | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.116); catalogued as COSV56521068; called by muse, mutect2, varscan2
- SUPV3L1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778772066, COSV62845754; called by muse, mutect2, varscan2
- TAF1L | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749284231, COSV54256396; called by mutect2, varscan2
- TBC1D31 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54865413; called by muse, mutect2, varscan2
- TCF20 | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 115/144 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs754587682, COSV100166279, COSV59493571; called by muse, mutect2, varscan2
- TCHHL1 | c.2131G>A p.G711R | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV64286424; called by muse, mutect2, varscan2
- TESMIN | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV54833679; called by muse, mutect2, varscan2
- TIRAP | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV67024390; called by muse, mutect2, varscan2
- TLE1 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as rs1171599646, COSV64690966; called by muse, mutect2, varscan2
- TMEM117 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV56909897; called by muse, mutect2, varscan2
- TMEM61 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64873701; called by muse, mutect2, varscan2
- TMEM67 | c.2975G>A p.R992K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60041582; called by muse, mutect2, varscan2
- TOX2 | c.1327C>T p.P443S (on ENST00000358131 / NM_001098798.2; = p.P419S on NM_032883.3) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57889433; called by muse, mutect2, varscan2
- TPTE | c.1173G>A p.K391= (on ENST00000618007 / NM_199261.4; = p.K373= on NM_199259.4) | Splice Region (SNP) | VAF 20/63 reads (32%) | catalogued as rs754185411; called by muse, mutect2, varscan2
- TRAPPC10 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV52378944, COSV99379368; called by muse, mutect2, varscan2
- TREM1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 43/67 reads (64%) | catalogued as COSV55148936; called by muse, mutect2, varscan2
- TRIM35 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs777215107, COSV59523486; called by muse, mutect2, varscan2
- TRIM58 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.127); catalogued as COSV63571160; called by muse, mutect2, varscan2
- TROAP | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV57744968; called by muse, varscan2
- TSGA10 | c.765A>C p.E255D | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV61824062; called by muse, mutect2, varscan2
- TSHZ2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs868436040, COSV61589752; called by mutect2, varscan2
- TTN | c.94820C>A p.T31607N (on ENST00000591111; = p.T24183N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | PolyPhen probably damaging (0.997); catalogued as COSV60168937; called by muse, mutect2, varscan2
- TTN | c.52576A>C p.N17526H (on ENST00000591111; = p.N10102H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV60168953; called by muse, mutect2, varscan2
- TTN | c.36430A>G p.T12144A (on ENST00000591111; = p.T4720A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | PolyPhen possibly damaging (0.647); catalogued as COSV60168972; called by mutect2, varscan2
- TTN | c.2957C>T p.S986F (on ENST00000591111; = p.S940F on NM_003319.4) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | PolyPhen probably damaging (0.998); catalogued as rs755373497, COSV60168993; called by muse, mutect2, varscan2
- UBE2U | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV64281224; called by muse, mutect2, varscan2
- UROC1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753007763, COSV52035514; called by muse, mutect2, varscan2
- USP43 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV99557153; called by muse, varscan2
- WAC | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.3); catalogued as rs867622037, COSV100611070, COSV61568232; called by muse, mutect2, varscan2
- WDR90 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99554329; called by mutect2, varscan2
- WLS | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99260787; called by mutect2, varscan2
- ZAN | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61813029; called by muse, varscan2
- ZAN | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV61811271; called by muse, mutect2, varscan2
- ZBED1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs771189505, COSV58130132; called by muse, mutect2, varscan2
- ZBP1 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV59062908; called by muse, mutect2, varscan2
- ZC3HAV1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs150932310; called by muse, mutect2, varscan2
- ZFAT | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64741414; called by muse, mutect2, varscan2
- ZFP3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV59583338; called by muse, mutect2, varscan2
- ZFP69B | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 120/236 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs759049040, COSV64315044; called by muse, mutect2, varscan2
- ZFPL1 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1369866214, COSV51870129; called by muse, mutect2, varscan2
- ZFYVE26 | c.6880A>G p.K2294E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV61330439; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs979537533, COSV60157592; called by muse, mutect2, varscan2
- ZNF208 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1163866186, COSV68109181, COSV68111424; called by mutect2, varscan2
- ZNF33A | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV56726252; called by muse, mutect2, varscan2
- ZNF408 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV61238651; called by muse, mutect2, varscan2
- ZNF568 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762810225, COSV61742066; called by muse, mutect2, varscan2
- ZNF573 | c.811G>A p.E271K (on ENST00000536220 / NM_001172692.1; = p.E213K on NM_152360.3) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs776046954, COSV59826540; called by muse, mutect2, varscan2
- ZNF578 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV69735865; called by muse, mutect2, varscan2
- ZNF592 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV55437952; called by muse, mutect2, varscan2
- ZNF607 | c.1909A>G p.S637G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62205671; called by muse, mutect2, varscan2
- ZNF609 | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.876); catalogued as COSV58579336; called by muse, mutect2, varscan2
- ZNF831 | c.4949G>A p.S1650N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as rs763051862, COSV64042126; called by muse, mutect2, varscan2
- ZSCAN2 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV57572410; called by muse, mutect2, varscan2
- ASAH2 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GAGE2E | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBGT1 | c.947_948del p.P316Rfs*80 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- IGHG3 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGHV1OR21-1 | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- KDR | c.3219_3220delinsG p.P1074Qfs*28 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | called by pindel, varscan2*
- LRSAM1 | c.1171_1173del p.Q391del | In Frame Del (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2
- MCF2L2 | c.2561_2582del p.K854Ifs*2 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- NUP205 | c.740_741del p.L247Pfs*12 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- OR5D13 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by pindel, varscan2
- SLC35F1 | c.331del p.T111Hfs*2 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.2521dup p.R841Pfs*33 | Frame Shift Ins (INS) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- TRGV8 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TSHR | c.1115del p.N372Tfs*40 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- ABCA6 | c.669T>C p.F223= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV52640856; called by muse, mutect2, varscan2
- ABCA8 | c.90C>T p.S30= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV52195791, COSV52207863; called by muse, mutect2
- AC011462.1 | c.681C>T p.V227= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV54198199; called by muse, mutect2, varscan2
- ACAN | c.2733C>T p.G911= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV61363760; called by muse, mutect2, varscan2
- ADAM28 | c.822G>A p.E274= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV56099330, COSV56100596; called by muse, mutect2, varscan2
- ADGRF5 | c.2361A>G p.V787= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV51936448; called by muse, mutect2, varscan2
- AGO1 | c.2034C>T p.L678= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs756047129, COSV64595734; called by muse, mutect2, varscan2
- AGXT | c.231C>T p.V77= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV56754826; called by muse, mutect2, varscan2
- ANKRD30A | c.1926C>T p.F642= (on ENST00000611781; = p.F586= on NM_052997.2) | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs557264466, COSV100652988, COSV64605804, COSV64615083; called by muse, mutect2, varscan2
- ARHGAP39 | c.2421C>T p.L807= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV52770437; called by muse, mutect2, varscan2
- ARHGAP6 | c.1839G>A p.L613= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as COSV57298473; called by mutect2, varscan2
- ARSG | c.246C>T p.S82= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV71593535; called by mutect2, varscan2
- ATF7IP | c.1473C>T p.A491= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV53773246; called by muse, mutect2, varscan2
- ATR | c.5856C>T p.L1952= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as rs778730760, COSV63388176; called by mutect2, varscan2
- BRD4 | c.3195G>C p.P1065= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99651602; called by muse, mutect2, varscan2
- BRINP2 | c.2172G>A p.R724= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV64178522; called by muse, mutect2, varscan2
- BUD13 | c.1002C>T p.S334= | Silent (SNP) | VAF 91/389 reads (23%) | catalogued as COSV52768739; called by muse, mutect2, varscan2
- C1GALT1C1 | c.111C>T p.H37= | Silent (SNP) | VAF 59/89 reads (66%) | catalogued as COSV58974442; called by muse, mutect2, varscan2
- C9 | c.1179A>G p.E393= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV54678411; called by muse, mutect2, varscan2
- CACNA1A | c.5502G>A p.L1834= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV64202792; called by muse, mutect2, varscan2
- CACNA1D | c.6363C>T p.P2121= (on ENST00000350061 / NM_001128840.3; = p.P2141= on NM_000720.4) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV55454245; called by muse, mutect2, varscan2
- CACNA1S | c.1284C>T p.I428= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs749688969, COSV100754528, COSV62938832; called by muse, mutect2, varscan2
- CALD1 | c.1494C>T p.F498= (on ENST00000361675 / NM_033138.4; = p.F243= on NM_004342.7) | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV100723983, COSV62649842; called by mutect2, varscan2
- CCDC88A | c.1425C>T p.T475= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs759145649, COSV55062220, COSV99710903; called by muse, mutect2, varscan2
- CCNJL | c.1080C>T p.S360= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV57444307, COSV57445567; called by muse, mutect2, varscan2
- CD163 | c.3195C>T p.F1065= | Silent (SNP) | VAF 58/115 reads (50%) | catalogued as rs763870346, COSV63129316; called by muse, mutect2, varscan2
- CD79A | c.57C>T p.F19= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1357221630, COSV55738657; called by muse, mutect2, varscan2
- CDHR3 | c.936C>T p.S312= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV58418927; called by muse, mutect2, varscan2
- CEACAM18 | c.936G>A p.R312= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV67282309; called by mutect2, varscan2
- CEACAM20 | c.444G>A p.R148= | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as COSV57602251; called by muse, mutect2, varscan2
- CENPJ | c.3966G>A p.R1322= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as COSV55042655; called by muse, mutect2, varscan2
- CEP250 | c.4959C>T p.L1653= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs1198658920, COSV61171488; called by muse, mutect2, varscan2
- CFAP57 | c.573C>T p.S191= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV65264831; called by muse, mutect2, varscan2
- CHODL | c.279G>A p.G93= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs767759893, COSV54733564; called by muse, mutect2, varscan2
- CHST4 | c.369C>T p.L123= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV58297626; called by muse, mutect2, varscan2
- CLIP2 | c.2272C>T p.L758= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV56281478; called by muse, mutect2, varscan2
- CMKLR1 | c.351C>T p.F117= (on ENST00000312143 / NM_001142344.2; = p.F115= on NM_004072.3) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV56439131; called by muse, mutect2, varscan2
- CNTNAP5 | c.1794G>A p.G598= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1263895829, COSV70494489; called by muse, mutect2, varscan2
- CNTRL | c.2767C>T p.L923= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV53049437, COSV99443816; called by muse, mutect2, varscan2
- COL27A1 | c.1767C>T p.A589= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV61928044; called by muse, mutect2, varscan2
- COL27A1 | c.5472C>T p.T1824= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100620754, COSV100620973, COSV61928051; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1128C>T p.F376= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as COSV65675978; called by muse, mutect2, varscan2
- CSMD2 | c.2850C>T p.C950= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV53928964; called by muse, mutect2, varscan2
- CYP2C9 | c.1206C>T p.P402= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as rs1459050142, COSV53250264, COSV99583325; called by muse, mutect2, varscan2
- DENND4A | c.4557C>T p.S1519= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs1287997497, COSV101475465; called by muse, mutect2, varscan2
- DISP3 | c.405G>A p.R135= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV53830914; called by muse, mutect2, varscan2
- DNAH5 | c.10107C>T p.F3369= | Silent (SNP) | VAF 54/63 reads (86%) | catalogued as COSV54224486, COSV54236601; called by muse, mutect2
- DPPA4 | c.546C>T p.S182= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV59511425; called by muse, mutect2, varscan2
- DSCAM | c.663G>A p.A221= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs767731476, COSV68024612; called by mutect2, varscan2
- DSG1 | c.2670G>A p.S890= | Silent (SNP) | VAF 62/87 reads (71%) | catalogued as rs771323370, COSV57137008; called by muse, mutect2, varscan2
- EFCAB6 | c.2721A>G p.E907= | Silent (SNP) | VAF 75/251 reads (30%) | catalogued as COSV53066561, COSV53071310; called by muse, mutect2, varscan2
- ENC1 | c.894C>T p.F298= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56628494; called by mutect2, varscan2
- EPHA6 | c.1923G>A p.Q641= (on ENST00000389672 / NM_001080448.3; = p.Q33= on NM_173655.4) | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs563022959, COSV67560959; called by muse, mutect2, varscan2
- EPPK1 | c.1860C>T p.S620= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV73261767; called by muse, mutect2, varscan2
- FAM135B | c.3006G>A p.E1002= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs369042238; called by muse, mutect2, varscan2
- FAM47B | c.342G>A p.R114= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV61455292; called by muse, mutect2, varscan2
- FAM50A | c.840C>T p.F280= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV50132067; called by mutect2, varscan2
- FANCA | c.3483G>A p.T1161= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs768306527, COSV59797275, COSV99981252; called by mutect2, varscan2
- FGFR4 | c.273C>T p.F91= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV52805839; called by muse, mutect2, varscan2
- FLG | c.5295C>T p.F1765= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as COSV64242100; called by muse, mutect2, varscan2
- FOLH1 | c.1056G>A p.V352= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs555590356, COSV57051768; called by mutect2, varscan2
- FOXRED2 | c.1419C>T p.P473= | Silent (SNP) | VAF 53/69 reads (77%) | catalogued as COSV53400668; called by muse, mutect2, varscan2
- FSD1 | c.861C>T p.S287= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs763117398, COSV55697010, COSV99696857; called by muse, mutect2, varscan2
- GALNT14 | c.645G>A p.R215= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs757175498, COSV61107353; called by muse, mutect2, varscan2
- GALNT17 | c.504C>T p.I168= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs747598824, COSV61170942; called by muse, mutect2, varscan2
- GALNT8 | c.654G>A p.L218= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV52898938, COSV52900137; called by muse, mutect2, varscan2
- GFRAL | c.556T>C p.L186= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs754755195, COSV61232595; called by muse, mutect2, varscan2
- GLI2 | c.708C>T p.S236= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV58045584; called by muse, mutect2, varscan2
- GLYR1 | c.846C>T p.I282= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs1567691599, COSV58925760; called by mutect2, varscan2
- GNA12 | c.837C>T p.T279= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs570479193, COSV51742776; called by muse, mutect2, varscan2
- GPR158 | c.1200C>T p.P400= | Silent (SNP) | VAF 87/120 reads (73%) | catalogued as rs377658822; called by muse, mutect2, varscan2
- GPR158 | c.2301G>C p.R767= | Silent (SNP) | VAF 39/55 reads (71%) | catalogued as COSV66274660; called by muse, mutect2, varscan2
- GRIA4 | c.384C>T p.S128= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs1320407745, COSV56880162, COSV56905602; called by muse, mutect2, varscan2
- H2BC21 | c.6T>C p.P2= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV58612505; called by muse, mutect2
- HEG1 | c.1248C>T p.S416= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV60763536; called by muse, mutect2, varscan2
- HPD | c.69C>T p.T23= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100000261; called by muse, mutect2, varscan2
- HRNR | c.8349C>T p.S2783= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs759827418, COSV64259951; called by muse, varscan2
- IFNLR1 | c.1125C>T p.V375= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV59526943; called by muse, mutect2, varscan2
- IL12RB1 | c.1455C>T p.C485= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100443249; called by muse, varscan2
- IL20RB | c.252C>T p.I84= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV59048543; called by muse, mutect2, varscan2
- IL7R | c.411C>T p.V137= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs545307253, COSV57407085; called by muse, mutect2, varscan2
- IQCA1 | c.1620C>T p.S540= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV54501506; called by muse, mutect2, varscan2
- KAT2B | c.1038C>T p.F346= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV55431404; called by muse, mutect2, varscan2
- KCNA4 | c.1947G>A p.V649= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV60253787; called by muse, mutect2, varscan2
- KCNJ8 | c.1251A>C p.G417= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99557772; called by muse, mutect2, varscan2
- KIAA1217 | c.2544C>T p.V848= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV56819118; called by muse, mutect2, varscan2
- KIAA1958 | c.1890C>T p.Y630= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV61725230; called by muse, mutect2, varscan2
- KIF6 | c.30G>A p.A10= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV54683887; called by muse, mutect2, varscan2
- KIR2DL4 | c.318G>A p.G106= (on ENST00000396284; = p.G67= on NM_001080770.2) | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs1420560921, COSV60878144; called by muse, mutect2, varscan2
- KLRC3 | c.420G>A p.E140= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV67250880; called by muse, mutect2, varscan2
- KMT2B | c.4434C>T p.H1478= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1171695506, COSV55864377; called by muse, mutect2, varscan2
- KRT3 | c.525C>T p.I175= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV100527390, COSV58816188; called by mutect2, varscan2
- KRTAP5-11 | c.255C>T p.S85= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV59370220; called by muse, mutect2, varscan2
- LAMB2 | c.5106A>G p.L1702= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1295938905, COSV59735184; called by muse, mutect2, varscan2
- LILRB1 | c.336G>A p.E112= (on ENST00000427581; = p.E76= on NM_006669.6) | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs561923750; called by muse, mutect2
- LILRB1 | c.1056C>T p.I352= (on ENST00000427581; = p.I316= on NM_006669.6) | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV61119481; called by muse, mutect2, varscan2
- LIMA1 | c.493C>T p.L165= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV57966617; called by muse, mutect2, varscan2
- LRP1B | c.12780A>C p.G4260= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV67243756; called by muse, mutect2, varscan2
- MAP2 | c.3420C>T p.L1140= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs777199689, COSV52297435; called by muse, mutect2, varscan2
- MAPK3 | c.753G>A p.L251= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV53774640; called by muse, mutect2, varscan2
- MMP11 | c.502C>T p.L168= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as rs1322039611, COSV53157036; called by muse, mutect2, varscan2
- MROH1 | c.2154C>T p.S718= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- MUC2 | c.3807C>T p.T1269= | Silent (SNP) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- MYH10 | c.4609C>T p.L1537= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs377742356; called by muse, mutect2, varscan2
- MYH4 | c.1617G>A p.E539= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV55121236; called by muse, mutect2, varscan2
- MYH8 | c.3405G>A p.A1135= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs78443907; called by muse, mutect2, varscan2
- NCKAP5 | c.5457C>T p.S1819= | Silent (SNP) | VAF 101/287 reads (35%) | catalogued as COSV58455957; called by muse, mutect2, varscan2
- NEB | c.8679G>A p.Q2893= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV51431047; called by muse, mutect2, varscan2
- NID1 | c.2859G>A p.K953= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV51623591, COSV51625707; called by muse, mutect2, varscan2
- NLRP7 | c.2163G>A p.R721= (on ENST00000340844 / NM_206828.3; = p.R693= on NM_139176.3) | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV60177064; called by muse, mutect2, varscan2
- NLRP7 | c.210G>A p.A70= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs111764628, COSV60177080; called by muse, mutect2, varscan2
- NPAP1 | c.1374C>T p.I458= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs902827866, COSV61507074; called by muse, mutect2, varscan2
- NR2F6 | c.351C>T p.F117= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1356424347, COSV99360328; called by muse, mutect2, varscan2
- NTRK3 | c.1881G>A p.K627= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs956906731, COSV62309308; called by muse, mutect2, varscan2
- NUP160 | c.2520C>T p.F840= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV65854941; called by muse, mutect2, varscan2
- NYNRIN | c.417G>A p.G139= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101230639; called by mutect2, varscan2
- OMA1 | c.1488G>A p.T496= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as rs772858754, COSV62256020; called by muse, mutect2, varscan2
- OR10G2 | c.90C>T p.L30= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs759794646, COSV73390416; called by muse, mutect2, varscan2
- OR10G8 | c.865C>T p.L289= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV101461898; called by muse, mutect2, varscan2
- OR10R2 | c.660C>T p.F220= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as rs781201339, COSV63768725; called by muse, mutect2, varscan2
- OR2M3 | c.375C>T p.A125= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as rs1421120977, COSV71758883; called by muse, mutect2, varscan2
- OR2T2 | c.291C>T p.G97= | Silent (SNP) | VAF 59/250 reads (24%) | catalogued as COSV61618467; called by muse, mutect2, varscan2
- OR2T34 | c.354C>T p.F118= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV60901027; called by muse, mutect2, varscan2
- OR4M1 | c.345C>T p.L115= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV60062336; called by mutect2, varscan2
- OR4N5 | c.486T>C p.L162= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV61320918; called by muse, mutect2, varscan2
- OR51A4 | c.816C>T p.L272= | Silent (SNP) | VAF 32/187 reads (17%) | catalogued as rs1285726571, COSV100985204, COSV66749743; called by muse, mutect2, varscan2
- OR51Q1 | c.900G>A p.Q300= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV56179770; called by muse, mutect2, varscan2
- OR52D1 | c.615G>A p.V205= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV59487855; called by muse, mutect2, varscan2
- OR52K1 | c.777C>T p.I259= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV56903654, COSV56904063; called by muse, mutect2, varscan2
- OR6B2 | c.282C>T p.F94= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs750021015, COSV53153142; called by mutect2, varscan2
- OR6X1 | c.822G>A p.V274= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV60010029; called by muse, mutect2, varscan2
- OR7E24 | c.561C>T p.F187= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV71702264; called by mutect2, varscan2
- OXTR | c.1020C>T p.L340= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs147196096; called by mutect2, varscan2
- PAK5 | c.1011G>A p.Q337= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV62031382; called by muse, mutect2, varscan2
- PBX1 | c.675C>T p.I225= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV63345532; called by muse, mutect2, varscan2
- PCDHA12 | c.957G>A p.Q319= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as COSV56502694; called by muse, mutect2, varscan2
- PCDHB4 | c.1677C>T p.F559= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs553336245, COSV52022887; called by muse, mutect2, varscan2
- PCDHB7 | c.2118C>T p.F706= | Silent (SNP) | VAF 55/175 reads (31%) | catalogued as rs868962799, COSV50753682; called by muse, mutect2, varscan2
- PCDHB8 | c.1683C>T p.F561= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs782576597, COSV50802007; called by mutect2, varscan2
- PCDHGB5 | c.1401C>T p.I467= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs749580875, COSV53918013; called by muse, mutect2, varscan2
- PCK1 | c.939C>T p.A313= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV60129475; called by muse, mutect2, varscan2
- PCLO | c.6903G>A p.V2301= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as COSV61646681; called by muse, mutect2, varscan2
- PCNX2 | c.4053G>A p.V1351= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV50786069; called by muse, mutect2, varscan2
- PHF13 | c.600C>T p.I200= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs781212968, COSV50011044; called by mutect2, varscan2
- PIGA | c.789A>G p.G263= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV61238009; called by muse, mutect2, varscan2
- PLB1 | c.24C>T p.F8= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs1366886943, COSV59822884; called by muse, mutect2, varscan2
- PLEKHG5 | c.2490C>T p.A830= (on ENST00000400915 / NM_001042663.3; = p.A793= on NM_020631.6) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV61068904; called by muse, mutect2, varscan2
- PLEKHG6 | c.1179G>A p.L393= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV50603932; called by muse, mutect2, varscan2
- POM121L12 | c.45C>T p.F15= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV68693385; called by mutect2, varscan2
- POM121L12 | c.762C>T p.S254= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs565805558, COSV101374918, COSV68693184, COSV68693801; called by muse, mutect2, varscan2
- PPP1R1C | c.24G>A p.K8= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV54717464; called by muse, mutect2, varscan2
- PRAMEF8 | c.57G>A p.R19= | Silent (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- PRG3 | c.234C>T p.A78= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs1415813456, COSV54664059; called by muse, mutect2, varscan2
- PRUNE2 | c.8430T>A p.L2810= | Silent (SNP) | VAF 62/176 reads (35%) | catalogued as COSV56317600; called by muse, mutect2, varscan2
- PRUNE2 | c.3354G>A p.V1118= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV65043520; called by mutect2, varscan2
- PSG3 | c.480G>A p.E160= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs777243753, COSV59504511, COSV59505373; called by muse, varscan2
- PTPN21 | c.2403C>T p.L801= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1478476981, COSV60849664; called by mutect2, varscan2
- RAC1 | c.99C>T p.I33= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as rs1240617392, COSV61821823; called by muse, mutect2, varscan2
- RBKS | c.21C>T p.P7= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100142547; called by muse, mutect2, varscan2
- RFX4 | c.546C>T p.P182= (on ENST00000392842 / NM_213594.3; = p.P88= on NM_032491.6) | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV57577513; called by muse, mutect2, varscan2
- RGS7 | c.966G>A p.P322= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs773183167, COSV58548420; called by mutect2, varscan2
- RGS7BP | c.651G>A p.R217= | Silent (SNP) | VAF 75/182 reads (41%) | catalogued as COSV100471153, COSV61835572; called by muse, mutect2, varscan2
- RHCG | c.936C>T p.V312= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV51516917; called by muse, mutect2, varscan2
- RP1 | c.4329G>A p.R1443= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs551846676, COSV55120468; called by muse, mutect2, varscan2
- RPL9 | c.516C>T p.I172= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV54696273; called by mutect2, varscan2
- RPS18 | c.168G>A p.A56= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs540397842, COSV65851473; called by muse, varscan2
- RYR3 | c.1209G>A p.E403= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV66798140; called by muse, mutect2, varscan2
- SCEL | c.1362C>T p.I454= (on ENST00000349847 / NM_144777.3; = p.I434= on NM_003843.4) | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV62992727, COSV62993939; called by muse, mutect2, varscan2
- SCG3 | c.585G>A p.E195= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1253637680, COSV55021931; called by muse, mutect2, varscan2
- SERPINA4 | c.861G>A p.R287= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV54070673; called by muse, mutect2, varscan2
- SETDB1 | c.1479C>T p.S493= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV54986904; called by muse, mutect2, varscan2
- SH3GL3 | c.474G>A p.L158= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1167473283, COSV61058617; called by mutect2, varscan2
- SIGLEC1 | c.1539C>T p.L513= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1377637577, COSV52472166; called by mutect2, varscan2
- SIGLEC1 | c.273G>A p.G91= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs370454342; called by muse, varscan2
- SIM1 | c.1557C>T p.V519= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV53490468, COSV53493873; called by muse, mutect2, varscan2
- SLC22A6 | c.1119C>T p.I373= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV64559862; called by muse, mutect2, varscan2
- SLC29A4 | c.498C>T p.Y166= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs373158173; called by mutect2, varscan2
- SLC6A3 | c.774C>T p.G258= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs751934788, COSV54366128; called by mutect2, varscan2
- SMIM8 | c.45C>A p.P15= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV57640662; called by mutect2, varscan2
- SNAPC4 | c.3921C>T p.A1307= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV53734680; called by muse, mutect2, varscan2
- SNRNP40 | c.690C>T p.T230= | Silent (SNP) | VAF 62/112 reads (55%) | catalogued as COSV55278320; called by muse, mutect2, varscan2
- SPEF2 | c.5040G>A p.E1680= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV57430304, COSV57432384; called by muse, mutect2
- STK10 | c.2544G>A p.E848= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV51576003; called by muse, mutect2, varscan2
- STRA6 | c.1215C>T p.P405= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV60584412; called by muse, mutect2, varscan2
- SULT1E1 | c.627C>T p.F209= | Silent (SNP) | VAF 45/72 reads (63%) | catalogued as COSV56946787, COSV56946872; called by muse, mutect2, varscan2
- SZT2 | c.2706C>T p.L902= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV65171380; called by muse, mutect2, varscan2
- TG | c.7770C>A p.I2590= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV55083411; called by mutect2, varscan2
- THSD7B | c.1848C>T p.S616= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV55707053; called by muse, mutect2, varscan2
- TMC5 | c.1986C>T p.F662= (on ENST00000396229 / NM_001105248.1; = p.F416= on NM_024780.5) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs746714550, COSV54906282; called by mutect2, varscan2
- TMEM120B | c.657C>T p.F219= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV61184526; called by muse, mutect2, varscan2
- TNR | c.3576G>A p.R1192= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs868458336, COSV54870628; called by muse, mutect2, varscan2
- TNXB | c.6345G>A p.T2115= (on ENST00000647633; = p.T1868= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/218 reads (21%) | catalogued as rs368704862, COSV64489222; called by muse, varscan2
- TRAF3IP3 | c.1158C>T p.D386= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV50555039; called by muse, mutect2, varscan2
- TRAT1 | c.375G>A p.R125= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs143422005, COSV55469414; called by muse, mutect2, varscan2
- TRAV12-3 | c.15G>A p.L5= | Silent (SNP) | VAF 15/46 reads (33%) | called by mutect2, varscan2
- TRBC2 | c.30G>A p.K10= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs549890187; called by muse, mutect2, varscan2
- TRIM61 | c.156C>T p.P52= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV61418442; called by muse, mutect2, varscan2
- TRPM2 | c.570C>T p.F190= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV55969437; called by muse, mutect2, varscan2
- TRPS1 | c.1581C>T p.F527= (on ENST00000220888 / NM_001330599.2; = p.F540= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV55249422; called by muse, mutect2, varscan2
- TSPOAP1 | c.492G>A p.R164= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV52112049; called by muse, mutect2, varscan2
- TTC26 | c.963C>T p.L321= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs545563186, COSV58272696; called by mutect2, varscan2
- UBE3C | c.379C>T p.L127= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV61951966, COSV61954404; called by muse, mutect2, varscan2
- UBXN10 | c.312C>T p.P104= | Silent (SNP) | VAF 53/96 reads (55%) | catalogued as COSV66772342; called by muse, mutect2, varscan2
- UNC13C | c.3951G>A p.R1317= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV52893447; called by muse, mutect2, varscan2
- XIRP2 | c.1785A>C p.A595= (on ENST00000628543; = p.A770= on NM_152381.6) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV54712942, COSV99744246; called by muse, mutect2, varscan2
- YLPM1 | c.6417C>T p.A2139= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV57821831; called by muse, mutect2, varscan2
- ZAN | c.1356C>T p.F452= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs768779642, COSV61805332; called by mutect2, varscan2
- ZBP1 | c.1071G>A p.E357= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs745740982, COSV100474126; called by muse, mutect2, varscan2
- ZFHX3 | c.10974C>T p.D3658= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs769344872, COSV51724527; called by mutect2, varscan2
- ZNF205 | c.603C>T p.V201= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV54621750; called by mutect2, varscan2
- ZNF470 | c.663C>T p.D221= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs936031962, COSV57969652; called by muse, mutect2, varscan2
- ZNF619 | c.18C>T p.P6= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV59030479; called by muse, mutect2, varscan2
- ZNF638 | c.1578C>T p.C526= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs762458208, COSV52491031; called by muse, varscan2
- ZPLD1 | c.921C>T p.P307= (on ENST00000466937 / NM_001329788.1; = p.P323= on NM_175056.2) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV60354627, COSV60355982; called by muse, mutect2, varscan2
- ZSWIM4 | c.1273C>T p.L425= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV54323634; called by muse, mutect2, varscan2
- AL136982.4 | n.427A>T | RNA (SNP) | VAF 126/194 reads (65%) | called by muse, mutect2, varscan2
- AL136982.4 | n.428C>T | RNA (SNP) | VAF 127/196 reads (65%) | catalogued as rs372313910; called by muse, mutect2, varscan2
- AL136982.4 | n.1368G>A | RNA (SNP) | VAF 61/81 reads (75%) | called by muse, mutect2, varscan2
- FBLN1 | c.1698-11345C>T | Intron (SNP) | VAF 55/67 reads (82%) | catalogued as rs1442847972, COSV53049916; called by muse, mutect2, varscan2
- FBXO16 | c.-1C>T | 5'UTR (SNP) | VAF 40/99 reads (40%) | catalogued as COSV100672525; called by muse, mutect2, varscan2
- KIR3DX1 | n.131G>A | RNA (SNP) | VAF 11/48 reads (23%) | catalogued as COSV55597955; called by muse, mutect2, varscan2
- KIR3DX1 | n.132G>A | RNA (SNP) | VAF 12/46 reads (26%) | catalogued as rs781397542, COSV55597967; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640920 G>A | 3'Flank (SNP) | VAF 11/23 reads (48%) | catalogued as rs781437368, COSV51705159; called by muse, mutect2, varscan2
- MIR543 | n.72C>T | RNA (SNP) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- PIK3R6 | c.-141G>A | 5'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100267015; called by muse, mutect2, varscan2
- RPL18A | c.329-200A>G | Intron (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99714542; called by muse, mutect2, varscan2
